Gene-level copy-number profile of tumor specimen AP-4LRG-8D from APOLLO case AP-4LRG, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3.
Specimen AP-4LRG-8D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 907e08ae-7e61-41d3-82a2-2fb16d1bd841.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-4LRG-GG (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/45b8237a-e0c9-4878-bae8-3eea3e9fc9e5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 275; copy number 1: 15,442; copy number 2: 37,742; copy number 3: 5,334; copy number 4: 77; copy number 5: 28.

Homozygous deletions (total copy number 0; autosomes only): 275 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,104,919–100,107,504, 1 gene (within-gene range 0–2): AC092667.1.
- chr3:13,937,273–14,082,811, 2 genes (within-gene range 0–1): TPRXL, AC090004.2.
- chr3:50,669,989–51,875,767, 24 genes: LINC02019, DOCK3, MIR4787, PPIAP69, AC126120.1, ZNF652P1, ST13P14, MANF, RBM15B, DCAF1, RAD54L2, RNU6ATAC29P, TEX264, AC099050.1, RNA5SP132, GRM2, IQCF6, AC097636.1, IQCF4P, IQCF3, IQCF2, RN7SL504P, IQCF5-AS1, IQCF5.
- chr11:1,074,875–1,201,138, 2 genes: MUC2, MUC5AC.
- chr11:45,215,815–45,691,776, 14 genes (within-gene range 0–1): AC103681.2, SYT13, AC103681.1, LINC02696, LINC02687, AC103855.3, AC018716.2, AC018716.1, AC103855.2, AC103855.4, AC103855.1, CHST1, AC087442.1, MIR7154.
- chr14:105,639,559–106,481,706, 130 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–2): IGHVIII-47-1, IGHV3-48.
- chr17:5,730,289–6,556,555, 12 genes: AC006236.1, AC007846.1, AC007846.2, WSCD1, AC104770.1, RNU6-1264P, BTF3P14, AIPL1, AC055872.1, PIMREG, PITPNM3, Metazoa_SRP.
- chr19:186,373–399,173, 9 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P, PLPP2, MIER2, AC016588.1, THEG, AC010641.1.
- chr19:53,599,628–54,063,953, 79 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:85,180,200–85,234,795, 1 gene, copy number 5 (within-gene range 3–5): AC044860.1.
- chr15:85,191,438–85,794,925, 21 genes, copy number 5: CSPG4P12, RN7SL428P, GOLGA6L3, ADAMTS7P4, AC044860.3, AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1.
- chr15:92,805,770–93,027,996, 6 genes, copy number 5 (within-gene range 3–5): AC106028.2, AC106028.4, CHASERR, AC013394.1, CHD2, MIR3175.

Autosomal genes at a single copy (total copy number 1): 12,586. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
